Somatic mutation profile of tumor specimen TCGA-G9-6338-01A (aliquot TCGA-G9-6338-01A-12D-1961-08) from TCGA case TCGA-G9-6338, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.2 years (22,360 days).
Specimen TCGA-G9-6338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8c5eb4b-10a6-4789-b9e7-eb9e09f64bd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6338-10A (Blood Derived Normal), aliquot TCGA-G9-6338-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d0e3b19-664a-4d33-a7e0-d33e4200621b

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 22, Silent 4, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC5 | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV55844658; called by muse, mutect2, varscan2
- ANKRD30A | c.3807T>G p.Y1269* (on ENST00000611781; = p.Y1213* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 3/44 reads (7%) | catalogued as COSV64618484; called by muse, mutect2
- ARFGAP1 | c.235G>T p.G79W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62263153; called by muse, varscan2
- BABAM2 | c.1037dup p.N346Kfs*12 | Frame Shift Ins (INS) | VAF 27/158 reads (17%) | catalogued as rs1477177585; called by mutect2, varscan2
- CDH3 | c.2470G>A p.G824S | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779881845, COSV50567637; called by muse, mutect2, varscan2
- CNOT2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.459); catalogued as rs750913052, COSV57506089; called by muse, mutect2, varscan2
- ENPP1 | c.1615A>G p.N539D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62935360; called by muse, mutect2, varscan2
- FADS3 | c.1309A>G p.I437V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53880088; called by muse, mutect2
- FBN3 | c.7578T>G p.C2526W | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54469797; called by muse, mutect2, varscan2
- HOXB13 | c.514T>G p.W172G | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51707011; called by muse, mutect2, varscan2
- HTT | c.4407+1G>C p.X1469_splice | Splice Site (SNP) | VAF 10/150 reads (7%) | catalogued as COSV61867685; called by muse, mutect2
- KIN | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65431322; called by muse, mutect2, varscan2
- MADD | c.4877C>T p.S1626L | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57032575; called by muse, mutect2, varscan2
- NCAPG2 | c.2983C>T p.Q995* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV51990922; called by muse, mutect2, varscan2
- OR1S2 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs769688464, COSV56920352; called by muse, varscan2
- PTPRG | c.2519T>G p.L840R | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV55658811; called by muse, mutect2, varscan2
- RGP1 | c.505T>G p.F169V | Missense Mutation (SNP) | VAF 40/468 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as COSV65240295; called by muse, mutect2
- SLC22A16 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV57933491; called by muse, mutect2, varscan2
- SLC51A | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs1309381681, COSV53059523; called by muse, mutect2
- SPOP | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61653211, COSV61655374; called by muse, mutect2, varscan2
- ST8SIA6 | c.685A>G p.K229E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66471171; called by muse, mutect2, varscan2
- UNC13D | c.507G>C p.E169D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.122); catalogued as COSV52882757, COSV52886777; called by muse, mutect2, varscan2
- WDCP | c.911G>C p.R304T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV54593466; called by muse, mutect2, varscan2
- WNK1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV60042849; called by muse, mutect2, varscan2
- ZNF142 | c.5151C>G p.C1717W (on ENST00000411696 / NM_001379660.1; = p.C1517W on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV68745143; called by muse, mutect2, varscan2
- ZNF765 | c.550C>A p.P184T | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.613); catalogued as COSV67183238; called by muse, mutect2
- ZNF827 | c.556A>C p.S186R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV65230837; called by muse, mutect2
- LCE2D | c.38del p.P13Lfs*61 | Frame Shift Del (DEL) | VAF 14/155 reads (9%) | called by mutect2, pindel
- SRSF1 | c.465dup p.G156Wfs*22 | Frame Shift Ins (INS) | VAF 18/70 reads (26%) | called by mutect2, pindel, varscan2
- AIFM2 | c.612G>T p.L204= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV57160388; called by muse, mutect2, varscan2
- GXYLT2 | c.1032C>T p.Y344= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs370320248; called by mutect2, varscan2
- HS3ST6 | c.798C>T p.F266= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as rs1174628789, COSV53533570; called by muse, mutect2
- NRCAM | c.96A>G p.V32= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as COSV61046348; called by muse, mutect2, varscan2
